Somatic mutation profile of tumor specimen TARGET-10-PATBDK-09A (aliquot TARGET-10-PATBDK-09A-01D) from TARGET case TARGET-10-PATBDK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.9 years (2,901 days).
Specimen TARGET-10-PATBDK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b64782e-1908-4fa9-9c0d-fae9c64ec53d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATBDK-10A (Blood Derived Normal), aliquot TARGET-10-PATBDK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1cceba6-7ca9-4e16-9960-185aa78134e3

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, RNA 1, Intron 1, In Frame Ins 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs864622341, COSV64290156; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2
- CSMD2 | c.3143G>A p.S1048N | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53954382; called by muse, mutect2, varscan2
- JPH4 | c.1154C>A p.A385E | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV58110343; called by muse, mutect2, varscan2
- LATS2 | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1278939497, COSV66879591; called by muse, mutect2, varscan2
- LINGO2 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs771681212, COSV58064119; called by muse, mutect2, varscan2
- MSI2 | c.295C>G p.R99G | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52357211, COSV52367499; called by muse, mutect2, varscan2
- MYB | c.40_41insCCA p.E14delinsAK | In Frame Ins (INS) | VAF 8/20 reads (40%) | catalogued as COSV57198855, COSV57201532, COSV57203337; called by mutect2, pindel, varscan2
- NDRG2 | c.479C>T p.P160L (on ENST00000298687 / NM_001354570.1; = p.P146L on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs144285486, COSV100069188, COSV53872977; called by muse, mutect2
- NEBL | c.1348A>G p.K450E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV65805586; called by muse, mutect2, varscan2
- PLXNA2 | c.2621C>T p.T874M | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs955150227, COSV65444671; called by muse, mutect2, varscan2
- PTEN | c.696_697insG p.R233Afs*10 | Frame Shift Ins (INS) | VAF 28/50 reads (56%) | catalogued as COSV64288717, COSV64289856, COSV64298421, COSV64299115, COSV64306382, COSV64307526, COSV99058011, COSV99058016, COSV99058020; called by mutect2, pindel*, varscan2
- ROBO2 | c.3578C>A p.P1193H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs1411421387, COSV59901891; called by muse, mutect2
- SLC12A6 | c.2003G>A p.R668Q (on ENST00000354181 / NM_001365088.1; = p.R617Q on NM_005135.2) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs779359867, COSV51631429; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF431 | c.980A>G p.Q327R | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs774365591, COSV60674353; called by muse, mutect2, varscan2
- CUL1 | c.1741_1751delinsGCTCTGGG p.W581_Q584delinsALG | In Frame Del (DEL) | VAF 18/40 reads (45%) | called by pindel, varscan2*
- LAMA3 | c.1672C>A p.R558= | Silent (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- OLA1 | c.1035T>C p.A345= | Silent (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- PHYHD1 | c.552C>T p.N184= (on ENST00000372592 / NM_001100876.2; = p.T177M on NM_174933.4) | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs755661083, COSV58282162; called by muse, mutect2, varscan2
- ARMC12 | c.163+14C>T | Intron (SNP) | VAF 32/67 reads (48%) | catalogued as rs781596502; called by muse, mutect2, varscan2
- MYADML | n.345C>T | RNA (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
